APOLLO case AP-NUWU — APOLLO2: Proteogenomic characterization of ovarian serous cystadenocarcinoma (APOLLO-OV)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Ovary.
https://portal.gdc.cancer.gov/cases/bb01954b-9af6-4baa-8fb8-cdb4f80daf0a

Demographics
Sex at birth: female; Race: white; Ethnicity: hispanic or latino; Age at index: 58 years; Vital status: Dead.

Diagnoses (1)
1. High-grade serous carcinoma: Tissue or organ of origin: Ovary; Site of resection or biopsy: Abdomen, NOS; Classification of tumor: metastasis; Age at diagnosis: 51.6 years (18,865 days); Residual disease: R1.

Biospecimens (2 samples)
- Sample AP-NUWU_normal: Tissue type: Normal; Specimen type: Peripheral Blood NOS; Biospecimen anatomic site: Other; Preservation method: Frozen.
- Sample AP-NUWU_tumor: Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Other; Preservation method: OCT; Diagnosis pathologically confirmed: Yes.
